Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3506, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3506-01A (Primary Tumor).

*** Diagnosis / Diagnoses: ***

Right hemicolectomy specimen with a colon carcinoma, of 4 cm in size at its maximum diameter, located approximately in the middle of the colon and not extending any closer than 10 cm to the aboral resection margin, and of the histological type of a moderately differentiated colorectal adenocarcinoma. Invasive spread of the tumor as far as the level of the muscularis propria. A tubulovillous colonic mucosal adenoma, of 2 cm in size at its maximum diameter and located 1 cm aboral to Bauhin's valve, with severe epithelial dysplasia (synonym: high-grade intra-epithelial neoplasia) and the remainder of the colonic mucosa also with individual tubular colonic mucosal adenomas with mild epithelial dysplasia (synonym: low-grade intra-epithelial neoplasia).

Appendix with post-inflammatory fibrosis of the wall and fibrosed obturation of the lumen.

Oral and aboral resection margins and large omentum tumor-free.

46 mesocolic and mesenteric lymph nodes tumor-free and with uncharacteristic reactive changes.

Tumor stage thus pT2 pN0 (0/46); G2

See preliminary histological findings

Source: NCI Genomic Data Commons file f37476a9-5a7b-42db-ad5d-36edaca095ae (TCGA-AA-3506.FD8D0605-1791-4A1F-95E2-AAD251B9BB02.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).